HCMI case HCM-CSHL-0814-C54 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/8853968f-f813-40ee-9084-cfd2e4ac854d

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Days to birth: -29,490 days (80.7 years before the index date); Year of birth: 1940; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Isthmus uteri; Classification of tumor: primary; AJCC staging edition: 8th; AJCC pathologic T: T2; AJCC pathologic N: N2mi; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC; FIGO stage: Stage IIIC; Tumor grade: G3; Prior malignancy: no; Prior treatment: No; Residual disease: R0; Peritoneal fluid cytological status: Non-Malignant; Sites of involvement: Cervix / Uterus / Pelvic Lymph Node(s) / Peri-aortic Lymph Node(s).
   Pathology details: Lymph node involvement: Positive; Lymphatic invasion present: Yes; Tumor largest dimension diameter: 6.8 cm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 42 days; Days to treatment end: 154 days.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 191 days; Days to treatment end: 230 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 629 days (1.7 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 241.

Molecular and laboratory tests
- ESR1 (IHC): Negative.
- MLH1 (IHC): Negative.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PMS2 (IHC): Negative.
- TP53 (IHC): Overexpressed.
- Test (Microsatellite Analysis): Low.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 91 kg; Height: 157.5 cm; BMI: 36.7.
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Risk factors: Diabetes, NOS / Adenomyosis.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0814-C54-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0814-C54-11A-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 6; Percent necrosis: 0; Percent stromal cells: 94; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0814-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
